CCDI case PBCWBI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/bcf8ecf2-aa5a-4fd8-bdfd-e365ea064e05

Demographics
Sex at birth: male.

Biospecimens (4 samples)
- Sample 0E1NYJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0E1O01, 0E25RO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1O0M: Tissue type: Tumor; Specimen type: Solid Tissue.
